CCDI case PBCMLA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/4453767f-3e5a-46c8-a1cf-4c302ddd24df

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Embryonal carcinoma, NOS: ICD-O-3 morphology code: 9070/3; Tissue or organ of origin: Cerebrum; Age at diagnosis: 3.4 years (1,258 days).

Biospecimens (2 samples)
- Sample 0DVJNP: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DVJON: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
